Somatic mutation profile of tumor specimen TCGA-TQ-A8XE-02A (aliquot TCGA-TQ-A8XE-02A-11D-A36O-08) from TCGA case TCGA-TQ-A8XE, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 42.8 years (15,629 days).
Specimen TCGA-TQ-A8XE-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1279da6-5ae8-4acf-8091-a5835e1526c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A8XE-10A (Blood Derived Normal), aliquot TCGA-TQ-A8XE-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7d9e42b-8ece-4da2-bf03-203f00a3325e

The open-access MAF lists 31 somatic variants for this specimen: 28 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 2, Nonsense Mutation 2, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 31/38 reads (82%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB9 | c.1697A>G p.D566G (on ENST00000280560 / NM_019625.4; = p.D523G on NM_019624.3) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99757578; called by muse, mutect2, varscan2
- ADGRG3 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs773580809, COSV100342106, COSV59652292; called by muse, mutect2, varscan2
- CDCP1 | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99943874; called by muse, mutect2, varscan2
- CHD8 | c.6592C>G p.L2198V (on ENST00000646647 / NM_001170629.2; = p.L1919V on NM_020920.4) | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs966821898, COSV100765269; called by muse, mutect2, varscan2
- CT55 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99358827; called by muse, mutect2, varscan2
- EPHB4 | c.2665C>G p.R889G | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.201); catalogued as rs762016655, COSV62268494, COSV62271028; called by muse, mutect2, varscan2
- GSK3B | c.1243T>A p.S415T (on ENST00000264235 / NM_001146156.2; = p.S428T on NM_002093.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.481); catalogued as COSV99954437; called by muse, mutect2
- KIAA0319 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV65496399; called by muse, mutect2, varscan2
- KRT20 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs201355464, COSV99391348; called by muse, mutect2
- LCT | c.3023T>C p.V1008A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV99928734; called by muse, mutect2, varscan2
- LRRC2 | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99947294; called by muse, mutect2
- MSI1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99981391; called by muse, mutect2, varscan2
- NFXL1 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1287450870, COSV100216691; called by muse, mutect2, varscan2
- OR4C6 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as COSV100051439; called by muse, mutect2, varscan2
- PCDHB5 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as rs1554275685, COSV99167673; called by muse, mutect2, varscan2
- RTTN | c.5075T>C p.L1692P | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99731283; called by muse, mutect2, varscan2
- SCD5 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV100124388; called by muse, mutect2, varscan2
- SIGLEC14 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as rs759989219, COSV55778956; called by muse, mutect2, varscan2
- SLC5A10 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100524852; called by muse, mutect2, varscan2
- TIMP1 | c.76T>A p.C26S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99512122; called by muse, mutect2, varscan2
- TMLHE | c.785A>G p.H262R | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100544614; called by muse, mutect2, varscan2
- TMTC3 | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99898142; called by muse, mutect2, varscan2
- TRMT2B | c.1168+1G>T p.X390_splice | Splice Site (SNP) | VAF 83/152 reads (55%) | catalogued as COSV100105212; called by muse, mutect2, varscan2
- WNK1 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60028112; called by muse, mutect2, varscan2
- ZNF578 | c.143T>C p.L48S | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101405026; called by muse, mutect2, varscan2
- RTN1 | c.2202_2206del p.L735Cfs*5 | Frame Shift Del (DEL) | VAF 21/29 reads (72%) | called by mutect2, pindel, varscan2
- EGF | c.3387T>C p.T1129= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV54479704; called by muse, mutect2, varscan2
- MXRA5 | c.1968G>A p.Q656= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as COSV99475993; called by muse, mutect2, varscan2
- MAP4 | c.1999+4699C>G | Intron (SNP) | VAF 11/59 reads (19%) | catalogued as rs557882920, COSV99274971; called by muse, mutect2, varscan2
